Gene-level copy-number profile of tumor specimen TCGA-BR-8373-01A from TCGA case TCGA-BR-8373, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 65.0 years (23,744 days).
Specimen TCGA-BR-8373-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.024aa539-11a4-4345-9649-29ea74aade89.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-8373-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4c6d8476-94dd-4840-9ad5-8a1550ff7900

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 1,315; copy number 2: 19,209; copy number 3: 24,864; copy number 4: 4,528; copy number 5: 8,310; copy number 6: 163; copy number 7: 1,325; copy number 8: 15; copy number 9: 18; copy number 10: 18; copy number 11: 19; copy number 12: 21.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-8373-01A-11D-2338-01): tumor purity 0.58, ploidy 2.97, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:32,076,114–32,882,830, 12 genes (within-gene range 0–2): ARHGAP5, AL161665.1, AL161665.2, RNU6-7, RNU6-8, AL136298.2, KIAA1143P1, AKAP6, AL136298.1, RN7SL660P, MTCO1P2, AL049781.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,416 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:36,837,698–37,157,065, 6 genes, copy number 8 (within-gene range 3–8): STRN, AC007382.1, RNU6-577P, HEATR5B, GPATCH11, EIF2AK2.
- chr2:176,989,418–177,559,299, 20 genes, copy number 7 (within-gene range 3–7): AC074286.1, AC079305.2, RNA5SP112, STUB1P1, Y_RNA, KRT8P40, HNRNPA3, MIR4444-1, NFE2L2, DNAJC19P5, MIR3128, AC079305.1, AC019080.1, AC019080.3, AC019080.4, MIR6512, AC019080.5, H3P7, AC019080.2, AGPS.
- chr2:218,270,392–218,346,793, 1 gene, copy number 7 (within-gene range 3–7): PNKD.
- chr2:218,326,889–218,568,351, 12 genes, copy number 7 (within-gene range 3–7): CATIP-AS2, MIR6810, RPL19P5, CATIP, CATIP-AS1, SLC11A1, CTDSP1, AC021016.2, MIR26B, VIL1, USP37, RN7SKP38.
- chr3:124,761,948–124,901,418, 1 gene, copy number 7 (within-gene range 5–7): ITGB5.
- chr3:124,862,094–125,388,997, 12 genes, copy number 7: ENO1P3, MUC13, HEG1, RNA5SP137, AC117488.1, SLC12A8, RNU6-230P, MIR5092, ZNF148, DUTP1, DNAJB6P7, RNU6-232P.
- chr3:131,985,855–132,660,082, 8 genes, copy number 8 (within-gene range 5–8): MIR5704, PSMC2P1, RPL7P16, ACP3, AC020633.1, NIP7P2, DNAJC13, ACAD11.
- chr3:132,597,270–132,618,967, 1 gene, copy number 8: ACKR4.
- chr5:58,198–8,157,788, 162 genes, copy number 7 (broad region; genes not listed).
- chr5:9,035,033–9,546,075, 1 gene, copy number 7 (within-gene range 5–7): SEMA5A.
- chr5:9,363,275–45,895,970, 522 genes, copy number 7 (broad region; genes not listed).
- chr6:143,422,832–143,511,720, 7 genes, copy number 7 (within-gene range 5–7): ADAT2, TUBB8P2, RNA5SP221, PEX3, AL031320.2, VDAC1P8, FUCA2.
- chr6:143,554,325–143,562,031, 1 gene, copy number 7: PHACTR2-AS1.
- chr7:17,299,295–17,940,501, 5 genes, copy number 7 (within-gene range 4–7): AC019117.3, AC019117.2, AC019117.1, AC006482.1, SNX13.
- chr7:66,809,993–67,239,519, 13 genes, copy number 7 (within-gene range 4–7): GTF2IRD1P1, AC027644.1, GTF2IP23, RNU6-1254P, LINC02604, AC073335.1, Metazoa_SRP, TMEM248, RN7SL43P, SBDS, TYW1, AC073089.1, MIR4650-1.
- chr11:2,129,112–2,158,391, 2 genes, copy number 7 (within-gene range 4–7): IGF2, AC132217.2.
- chr11:2,132,538–2,173,138, 6 genes, copy number 7: INS-IGF2, MIR483, IGF2-AS, INS, TH, MIR4686.
- chr11:102,110,447–102,727,050, 18 genes, copy number 9 (within-gene range 3–9): YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8.
- chr13:51,908,218–52,476,628, 20 genes, copy number 7 (within-gene range 5–7): CTAGE3P, AL162377.2, ATP7B, FABP5P2, ALG11, UTP14C, NEK5, AL139082.1, NEK3, MRPS31P5, AL158066.1, THSD1P1, AL158066.2, TPTE2P2, LINC02333, THSD1, RNY4P24, VPS36, AL359513.1, CKAP2.
- chr13:73,036,401–73,408,352, 8 genes, copy number 7: PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12.
- chr17:32,265,832–32,412,420, 11 genes, copy number 7: RHBDL3, AC026620.1, AC005899.4, C17orf75, AC005899.3, OOSP1P2, MIR632, ZNF207, AC005899.6, AC005899.7, AC005899.5.
- chr19:18,097,793–18,369,950, 18 genes, copy number 10: MAST3, AC007192.2, AC007192.1, PIK3R2, IFI30, MPV17L2, RAB3A, AC005759.1, AC008397.2, PDE4C, AC008397.1, IQCN, JUND, MIR3188, RPL39P38, LSM4, RN7SL513P, PGPEP1.
- chr20:43,304,555–64,313,132, 561 genes, copy number 7–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,315. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
